Somatic mutation profile of tumor specimen C3L-01455-01 (aliquot CPT0108560009) from CPTAC case C3L-01455, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 88.5 years (32,312 days).
Specimen C3L-01455-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 520df746-7f36-4534-aa37-e61ece281c97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01455-31 (Blood Derived Normal), aliquot CPT0108340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/744df279-a26e-41db-9eb5-adaf46746158

The open-access MAF lists 191 somatic variants for this specimen: 139 protein-altering or splice-affecting, 29 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 29, Intron 13, Nonsense Mutation 13, Splice Site 4, RNA 4, 5'UTR 3, 3'UTR 2, Frame Shift Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEN1 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs104894267, CM970941, COSV53642158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV99960852; called by muse, mutect2
- AK9 | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV58141326; called by muse, mutect2
- AMBN | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1273233451; called by muse, mutect2, varscan2
- ASPM | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV54128331, COSV99659393; called by muse, varscan2
- CACNA1I | c.4183G>A p.V1395M | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60800476; called by muse, mutect2
- CACNA2D4 | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as rs373327688; called by muse, mutect2, varscan2
- CARF | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.692); catalogued as COSV57548830; called by muse, mutect2, varscan2
- CHD2 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100560678; called by muse, mutect2
- CLCNKB | c.1298-1G>T p.X433_splice | Splice Site (SNP) | VAF 59/363 reads (16%) | catalogued as COSV65161724; called by muse, mutect2, varscan2
- CLCNKB | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071617, COSV65159818; called by muse, mutect2, varscan2
- CRY2 | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1192572712; called by muse, mutect2
- CTPS1 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65453295; called by muse, mutect2
- DGKB | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV51805011; called by muse, mutect2
- DLC1 | c.2279C>T p.T760M (on ENST00000276297 / NM_001348081.2; = p.T323M on NM_006094.5) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs144923726, COSV104371038; called by muse, varscan2
- DLC1 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99361581; called by muse, mutect2
- DST | c.7276C>T p.H2426Y | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV99757899; called by muse, mutect2, varscan2
- FN3K | c.854A>T p.Y285F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV56181964; called by muse, mutect2
- FNTA | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs368301964; called by muse, mutect2, varscan2
- GC | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56739654, COSV99909919; called by muse, mutect2, varscan2
- GIN1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV101204364; called by muse, mutect2
- GPR75 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs745629092, COSV61829458; called by muse, mutect2
- GSPT1 | c.1114G>C p.E372Q (on ENST00000420576 / NM_001130007.2; = p.E510Q on NM_002094.4) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV70452692, COSV70452706; called by muse, mutect2, varscan2
- JPH3 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs750758694, COSV52468986; called by muse, mutect2, varscan2
- KIF17 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56116382, COSV56123615; called by muse, mutect2, varscan2
- KMT2D | c.12253C>T p.Q4085* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | catalogued as COSV56413441; called by muse, mutect2
- LAMA1 | c.4807G>C p.E1603Q | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as COSV67539796; called by muse, mutect2
- LRRC15 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs781238952; called by muse, mutect2, varscan2
- MIA2 | c.2170C>G p.P724A | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV54496331; called by muse, mutect2
- MORC3 | c.461-1C>T p.X154_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | catalogued as rs1213250631, COSV68688707; called by muse, mutect2
- MRPL9 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs748907367; called by muse, mutect2, varscan2
- NR2C2AP | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57393675; called by muse, mutect2
- PLCD3 | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs777313442, COSV51962024; called by muse, mutect2
- PLS3 | c.795G>C p.M265I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56782038; called by muse, mutect2, varscan2
- PPIG | c.897del p.N301Tfs*25 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | catalogued as COSV53641564; called by mutect2, pindel
- REP15 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs779970048; called by muse, mutect2, varscan2
- RLF | c.4996C>G p.L1666V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101034965; called by muse, mutect2
- RPS10-NUDT3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.988); catalogued as rs892294131; called by muse, mutect2, varscan2
- SRCAP | c.2304G>C p.Q768H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.191); catalogued as COSV52677394; called by muse, varscan2
- TDG | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753641238, COSV99904318; called by muse, mutect2
- TKT | c.1240G>T p.G414C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56245078; called by muse, mutect2, varscan2
- TMC6 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs749657465; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF518B | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV58722312, COSV58722747; called by muse, mutect2, varscan2
- ZNF615 | c.2080G>C p.G694R | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.36); catalogued as rs1303803097; called by muse, mutect2, varscan2
- ZNF862 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV56222612; called by muse, mutect2
- ADGRL1 | c.3423C>G p.Y1141* (on ENST00000340736 / NM_001008701.3; = p.Y1136* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- AFDN | c.5373C>G p.F1791L (on ENST00000447894 / NM_001366320.1; = p.F1710L on NM_001207008.1) | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- AKAP6 | c.1091G>T p.C364F | Missense Mutation (SNP) | VAF 19/281 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2
- ALG3 | c.336C>G p.Y112* | Nonsense Mutation (SNP) | VAF 65/231 reads (28%) | called by muse, mutect2, varscan2
- ANAPC1 | c.3728T>C p.L1243P | Missense Mutation (SNP) | VAF 20/521 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ARHGAP5 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ASPM | c.7248T>A p.S2416R | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.348); called by muse, mutect2
- ASTN1 | c.1218C>A p.C406* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- C5AR1 | c.367A>C p.S123R | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C9 | c.142T>A p.W48R | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D1 | c.2633T>A p.I878N (on ENST00000356253 / NM_001366867.1; = p.I866N on NM_000722.4) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- CATSPERE | c.1591C>G p.H531D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CBLB | c.2567C>G p.S856* | Nonsense Mutation (SNP) | VAF 13/329 reads (4%) | called by muse, mutect2
- CCDC168 | c.17356G>C p.D5786H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); called by muse, mutect2
- CCDC96 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.065); called by mutect2, varscan2
- CCN2 | c.679T>A p.S227T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- CDK11A | c.1013-1G>A p.X338_splice (on ENST00000378633 / NM_001313896.2; = p.X335_splice on NM_024011.4) | Splice Site (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- CENPF | c.7392T>A p.C2464* | Nonsense Mutation (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- CES1 | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 32/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP54 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2
- CHRNA3 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- DCDC1 | c.2099G>C p.S700T | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- DEDD2 | c.800T>A p.L267Q | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- DOCK10 | c.2207A>G p.H736R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ECRG4 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELFN2 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EML5 | c.1511C>G p.S504* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- ENGASE | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FAM155A | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM76A | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- FBXO27 | c.480G>C p.W160C | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FCGR3B | c.246C>A p.N82K | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHOD3 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2
- FMNL2 | c.564T>G p.S188R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2
- FOXN3 | c.153A>C p.E51D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- GBP6 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- HAO1 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2
- HIVEP1 | c.5490G>C p.L1830F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ISL2 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- ITGA9 | c.2602C>G p.Q868E | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.241); called by muse, mutect2
- ITGB2 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KDM6A | c.3737C>G p.A1246G | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2
- KIF17 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- KIRREL3 | c.1491C>A p.Y497* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- KRT73 | c.615C>G p.D205E | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KRT76 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MAGEL2 | c.3490C>A p.Q1164K | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MBLAC2 | c.440T>A p.L147H | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2
- MEFV | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.284); called by muse, mutect2
- NBR1 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- NMU | c.505A>T p.R169W | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPR1 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- OPN3 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR6T1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- PDZD8 | c.2956G>A p.G986S | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.634); called by muse, mutect2
- PGD | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- PITRM1 | c.2765C>G p.S922C | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PLA2G4D | c.1130C>A p.S377* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- PTCHD4 | c.1819C>G p.R607G | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- RAB30 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- RGS9 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RHOBTB2 | c.2153C>G p.S718* | Nonsense Mutation (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- RNF213 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.103); called by muse, mutect2
- RP1 | c.3361A>C p.M1121L | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); called by muse, mutect2
- RRM1 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- RUNDC1 | c.1694T>A p.I565N | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- RYR2 | c.8406C>G p.N2802K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR3 | c.925dup p.A309Gfs*85 | Frame Shift Ins (INS) | VAF 27/203 reads (13%) | called by mutect2, pindel, varscan2
- SERPINA1 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- SF3B2 | c.1945A>G p.K649E | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SIVA1 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC25A19 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- SLC7A14 | c.787T>C p.Y263H | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEN | c.2005T>G p.Y669D | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- SRRM1 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- STAMBP | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- STK36 | c.501G>T p.M167I | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D2 | c.2713G>C p.E905Q (on ENST00000465784 / NM_001267571.2; = p.E894Q on NM_018421.4) | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBXA2R | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TIGIT | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNK2 | c.234+1G>A p.X78_splice | Splice Site (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- TOPBP1 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- TOX3 | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- UROS | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- UTP20 | c.4909A>G p.T1637A | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VPS13D | c.9344A>G p.H3115R | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2
- VWF | c.7163G>T p.C2388F | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- WDR72 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ZAR1 | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ZBTB41 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- ZFAT | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF117 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2
- ZNF217 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF583 | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTN1 | c.1842G>A p.R614= | Silent (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- ANKRD11 | c.2175C>T p.N725= | Silent (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- CACFD1 | c.504G>C p.L168= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.3897C>T p.N1299= (on ENST00000236925 / NM_001297707.2; = p.N1288= on NM_203459.3) | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs768512460, COSV52670269; called by muse, mutect2
- CCDC160 | c.537A>G p.K179= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- CUEDC1 | c.1023G>A p.L341= | Silent (SNP) | VAF 28/255 reads (11%) | called by muse, mutect2, varscan2
- DNAH9 | c.8286T>G p.G2762= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- ELFN2 | c.1398C>T p.P466= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs779577089, COSV68743926, COSV68745375; called by muse, mutect2, varscan2
- EPHA1 | c.927C>A p.T309= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- FAM193B | c.240G>A p.Q80= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- FBN3 | c.1671C>T p.C557= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- FCGR2B | c.879A>T p.S293= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- FOSB | c.703C>T p.L235= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, varscan2
- GPATCH8 | c.1552C>T p.L518= | Silent (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- HAO1 | c.900T>G p.V300= | Silent (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- HEPHL1 | c.873C>T p.S291= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- HNRNPA1L2 | c.621A>G p.G207= | Silent (SNP) | VAF 33/321 reads (10%) | called by muse, mutect2, varscan2
- HUS1 | c.438A>G p.L146= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs1395187342; called by muse, mutect2, varscan2
- MACF1 | c.19551G>C p.L6517= (on ENST00000372915; = p.L4562= on NM_012090.5) | Silent (SNP) | VAF 12/353 reads (3%) | catalogued as COSV57125353; called by muse, mutect2
- MAP1A | c.2199T>C p.S733= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- MAP3K1 | c.3339C>T p.F1113= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV68124434; called by muse, mutect2, varscan2
- MYEOV | c.174C>G p.L58= | Silent (SNP) | VAF 355/467 reads (76%) | catalogued as COSV58293428; called by muse, mutect2, varscan2
- NIM1K | c.229C>A p.R77= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV58139161; called by muse, mutect2, varscan2
- PPP1R12A | c.1944G>A p.L648= | Silent (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- STK36 | c.3469C>T p.L1157= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV55325066; called by muse, mutect2
- TEDC1 | c.495C>A p.V165= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV57635062; called by muse, mutect2
- TRAV18 | c.335A>G p.*112= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs983008036; called by muse, mutect2, varscan2
- TTN | c.47334T>A p.I15778= (on ENST00000591111; = p.I8354= on NM_003319.4) | Silent (SNP) | VAF 59/383 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.11031A>G p.G3677= (on ENST00000591111; = p.G3631= on NM_003319.4) | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- ATP11AUN | n.810C>A | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- ATP11AUN | n.811C>A | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- FAM20C | c.864-17958C>T | Intron (SNP) | VAF 10/113 reads (9%) | catalogued as rs1264093349; called by muse, mutect2
- FOXP2 | chr7:114086382 G>C | 5'Flank (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- GALNT9 | c.1077+46G>A | Intron (SNP) | VAF 43/298 reads (14%) | catalogued as rs782117150; called by muse, mutect2, varscan2
- GGH | c.360+41G>A | Intron (SNP) | VAF 23/182 reads (13%) | catalogued as rs1040026220; called by muse, mutect2, varscan2
- GPBP1 | c.478+1073C>T | Intron (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- HMGN2 | c.-85G>C | 5'UTR (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
- IGFN1 | c.1242-2974G>T | Intron (SNP) | VAF 13/212 reads (6%) | catalogued as rs1195456153; called by muse, mutect2
- MRPL55 | c.26+159C>G | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- NBPF25P | n.936A>G | RNA (SNP) | VAF 26/571 reads (5%) | called by muse, mutect2
- OBSCN | c.18661+3126C>T | Intron (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- PPP2R5C | c.93+2267T>G | Intron (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- PTK2 | c.1417+307G>T | Intron (SNP) | VAF 13/172 reads (8%) | catalogued as rs530514449; called by muse, mutect2
- RPL12 | c.293-118C>G | Intron (SNP) | VAF 25/216 reads (12%) | called by muse, mutect2, varscan2
- S100A1 | c.-50G>T | 5'UTR (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+173G>A | Intron (SNP) | VAF 26/360 reads (7%) | called by muse, mutect2
- SEPTIN7P9 | n.349-993G>C | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*422A>G | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- SRSF10 | c.438-14G>C | Intron (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- TMEM160 | c.*7C>G | 3'UTR (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- TRHR | c.-5T>C | 5'UTR (SNP) | VAF 11/237 reads (5%) | catalogued as rs1250169231; called by muse, mutect2
- TUBBP5 | n.921G>A | RNA (SNP) | VAF 33/201 reads (16%) | catalogued as rs758902513; called by muse, mutect2, varscan2
